Somatic mutation profile of tumor specimen TCGA-VQ-A8PT-01A (aliquot TCGA-VQ-A8PT-01A-11D-A410-08) from TCGA case TCGA-VQ-A8PT, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 65.2 years (23,797 days).
Specimen TCGA-VQ-A8PT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a359b31-3c2e-45f4-9595-c2dd5546c150.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8PT-10A (Blood Derived Normal), aliquot TCGA-VQ-A8PT-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3db34ece-4a3c-48e5-a140-4ffb33f114be

The open-access MAF lists 1,620 somatic variants for this specimen: 1,224 protein-altering or splice-affecting, 353 silent, 43 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 758, Silent 353, Frame Shift Del 329, Frame Shift Ins 59, Nonsense Mutation 40, Intron 18, Splice Site 17, In Frame Del 16, RNA 6, 5'Flank 6, 3'UTR 5, 3'Flank 4.

Variants (750 of 1,620; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- APOA1 | c.85del p.Q29Rfs*7 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | catalogued as rs753348565, CD961783; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CLCN2 | c.1143del p.G382Afs*34 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as rs863225252, CD135843; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FLCN | c.1285del p.H429Tfs*39 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs80338682, CD023282, CM082680; ClinVar: pathogenic; called by mutect2, varscan2
- FLNB | c.1592del p.G531Dfs*42 | Frame Shift Del (DEL) | VAF 11/43 reads (26%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- GRM1 | c.26del p.F9Sfs*119 | Frame Shift Del (DEL) | VAF 48/134 reads (36%) | catalogued as rs758809498; ClinVar: pathogenic; called by mutect2, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MSH6 | c.3261del p.F1088Sfs*2 | Frame Shift Del (DEL) | VAF 30/78 reads (38%) | hotspot (GDC flag); catalogued as rs267608078, COSV99029757; ClinVar: pathogenic; called by mutect2, varscan2
- PPT1 | c.166dup p.M56Nfs*45 (on ENST00000433473; = p.M57Nfs*45 on NM_000310.4) | Frame Shift Ins (INS) | VAF 26/84 reads (31%) | catalogued as rs386833634; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PTEN | c.968del p.N323Mfs*21 | Frame Shift Del (DEL) | VAF 63/162 reads (39%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- RPGRIP1L | c.1329del p.K443Nfs*3 | Frame Shift Del (DEL) | VAF 17/38 reads (45%) | catalogued as rs749987648; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RRAS2 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs782457908, COSV56329532; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SACS | c.5151del p.K1717Nfs*8 | Frame Shift Del (DEL) | VAF 18/39 reads (46%) | catalogued as rs754439135, CD1515371; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- SLCO2A1 | c.830del p.F277Sfs*8 | Frame Shift Del (DEL) | VAF 32/82 reads (39%) | catalogued as rs751192029; ClinVar: pathogenic; called by mutect2, varscan2
- AADAC | c.1051A>G p.M351V | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1188410286, COSV99232998; called by muse, mutect2, varscan2
- AAMP | c.44del p.P15Hfs*5 | Frame Shift Del (DEL) | VAF 86/281 reads (31%) | catalogued as rs751284215; called by mutect2, pindel, varscan2
- AASDH | c.1936del p.R646Gfs*22 | Frame Shift Del (DEL) | VAF 52/154 reads (34%) | catalogued as rs1560573263; called by mutect2, pindel, varscan2
- ABCA12 | c.4930G>A p.D1644N (on ENST00000272895 / NM_173076.3; = p.D1326N on NM_015657.3) | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV99787559; called by muse, mutect2, varscan2
- ABCA2 | c.5107G>A p.D1703N (on ENST00000614293; = p.D1673N on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.276); catalogued as rs752850115, COSV55807750; called by muse, mutect2, varscan2
- ABCA7 | c.5836G>A p.V1946M | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.48); catalogued as COSV54028168; called by muse, mutect2
- ABCB6 | c.953del p.G318Vfs*9 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs777439793; called by mutect2, varscan2
- ABCB6 | c.14G>A p.G5D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.006); catalogued as COSV99521338; called by muse, varscan2
- ABCC11 | c.2279C>T p.A760V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as rs1192378299, COSV100750419; called by muse, mutect2, varscan2
- ABCC2 | c.1463A>G p.Q488R | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100966319; called by muse, mutect2, varscan2
- ABL2 | c.709C>T p.R237C (on ENST00000502732 / NM_007314.4; = p.R222C on NM_005158.5) | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs781311580, COSV100772255; called by muse, mutect2, varscan2
- ABT1 | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1554144825, COSV99223057; called by muse, mutect2, varscan2
- AC011448.1 | c.44del p.G15Afs*24 | Frame Shift Del (DEL) | VAF 18/57 reads (32%) | catalogued as rs751852332, COSV99388847; called by mutect2, pindel, varscan2
- ACP2 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.923); catalogued as rs985472476, COSV99922040; called by muse, varscan2
- ACSS3 | c.239C>A p.A80D | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99698007; called by muse, mutect2, varscan2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 30/70 reads (43%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ADA | c.944T>C p.M315T | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs758501653, COSV100596037; called by muse, mutect2, varscan2
- ADAM8 | c.1651G>A p.V551I | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.022); catalogued as rs1324783661, COSV69864716; called by muse, mutect2, varscan2
- ADAMTS1 | c.2701A>G p.T901A | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0.038); catalogued as COSV99535688; called by muse, mutect2, varscan2
- ADAMTS18 | c.2085del p.F695Lfs*7 | Frame Shift Del (DEL) | VAF 12/65 reads (18%) | catalogued as rs772504358, COSV51414270; called by mutect2, varscan2
- ADAMTS18 | c.1713G>C p.W571C | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99270742; called by muse, mutect2, varscan2
- ADAMTS18 | c.1391C>G p.T464R | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99270746; called by muse, mutect2, varscan2
- ADAMTS2 | c.2036G>A p.R679H | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs144554943, COSV52381631; called by muse, mutect2, varscan2
- ADAMTSL4 | c.963dup p.T322Dfs*10 | Frame Shift Ins (INS) | VAF 6/12 reads (50%) | catalogued as rs748115277; called by mutect2, varscan2
- ADAT3 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs762106841, COSV100280095; called by muse, mutect2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 21/67 reads (31%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRB2 | c.1417+2T>C p.X473_splice | Splice Site (SNP) | VAF 24/65 reads (37%) | catalogued as COSV99925487; called by muse, mutect2, varscan2
- ADGRF4 | c.160G>T p.G54* | Nonsense Mutation (SNP) | VAF 24/76 reads (32%) | catalogued as COSV99347875; called by muse, mutect2, varscan2
- ADGRG7 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs760536302, COSV99840333; called by muse, mutect2, varscan2
- ADGRL1 | c.902G>A p.R301H (on ENST00000340736 / NM_001008701.3; = p.R296H on NM_014921.5) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201495192, COSV100529155; called by muse, mutect2, varscan2
- ADGRL3 | c.731C>T p.P244L (on ENST00000506720 / NM_001322402.2; = p.P176L on NM_015236.6) | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72267883, COSV72268912; called by muse, mutect2, varscan2
- ADH5 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs1313760014, COSV99596057; called by muse, mutect2, varscan2
- ADRA2A | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.426); catalogued as COSV99701374; called by muse, mutect2
- AFF4 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV54794623, COSV99534431; called by muse, mutect2, varscan2
- AHDC1 | c.3766G>A p.A1256T | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs147020238; called by muse, mutect2, varscan2
- AHNAK | c.8242G>A p.V2748M | Missense Mutation (SNP) | VAF 89/244 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as COSV99945044; called by muse, mutect2, varscan2
- AHNAK | c.1735G>A p.A579T | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.953); catalogued as COSV99945046; called by muse, mutect2, varscan2
- AK5 | c.905G>A p.R302H (on ENST00000354567 / NM_174858.3; = p.R276H on NM_012093.4) | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs529896590, COSV100642274; called by muse, mutect2, varscan2
- AK7 | c.1961G>A p.R654H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.132); catalogued as rs1312635868, COSV50870898, COSV99966862; called by muse, mutect2, varscan2
- ALB | c.912A>T p.E304D | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs761031075, COSV99890388; called by muse, mutect2, varscan2
- ALCAM | c.1577C>T p.A526V | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100064000; called by muse, mutect2, varscan2
- ALDH3B2 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs371403715; called by muse, mutect2
- ALG5 | c.314T>C p.V105A | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1269583938, COSV99523463; called by muse, mutect2, varscan2
- AMER3 | c.1669dup p.A557Gfs*54 | Frame Shift Ins (INS) | VAF 12/28 reads (43%) | catalogued as rs756385870; called by mutect2, varscan2
- ANAPC4 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1049504668, COSV100193701; called by muse, varscan2
- ANAPC7 | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs939569596, COSV101482828; called by muse, mutect2, varscan2
- ANGEL1 | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.053); catalogued as rs775354721, COSV51873019; called by muse, mutect2, varscan2
- ANGPTL1 | c.979G>A p.G327S | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141519919; called by muse, mutect2, varscan2
- ANK2 | c.4253G>A p.R1418H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770698838, COSV99998717; called by muse, mutect2, varscan2
- ANK3 | c.2938A>G p.I980V (on ENST00000280772 / NM_001320874.2; = p.I114V on NM_001149.3) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs375406302; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3103T>C p.S1035P | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99781661; called by muse, mutect2, varscan2
- ANKLE2 | c.1754G>A p.G585D | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.039); catalogued as COSV100513850; called by muse, mutect2, varscan2
- ANKRD11 | c.7735C>T p.R2579C | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1567537413, COSV56358396; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKRD11 | c.6038C>T p.A2013V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.019); catalogued as rs745685018, COSV56366882; called by muse, mutect2, varscan2
- ANKRD11 | c.3827C>T p.A1276V | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs762783165, COSV56361542; called by muse, mutect2, varscan2
- ANKRD17 | c.7229G>A p.G2410E | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.261); catalogued as COSV100428267, COSV100428931; called by muse, mutect2, varscan2
- ANKRD35 | c.2695C>T p.R899W | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV62910844; called by muse, mutect2, varscan2
- ANKRD54 | c.547+2T>C p.X183_splice | Splice Site (SNP) | VAF 23/67 reads (34%) | catalogued as COSV99316303; called by muse, mutect2, varscan2
- ANKRD55 | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.998); catalogued as COSV100590945; called by muse, mutect2, varscan2
- ANKS3 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as rs776169640, COSV100422800; called by muse, varscan2
- ANKS6 | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.031); catalogued as rs747669510, COSV100782205; called by muse, mutect2, varscan2
- ANO3 | c.1592C>T p.T531M | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs1352571478, COSV99879605; called by muse, mutect2, varscan2
- ANO4 | c.2312A>G p.Y771C (on ENST00000392977 / NM_001286615.2; = p.Y736C on NM_178826.4) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as COSV100151255; called by muse, mutect2, varscan2
- AP1G1 | c.2012C>A p.A671D | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100249906; called by muse, mutect2, varscan2
- APOB | c.5580G>T p.Q1860H | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs199585500, COSV51931554; called by muse, mutect2, varscan2
- APP | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV100695122, COSV61004969; called by muse, mutect2, varscan2
- ARFGAP1 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.116); catalogued as rs746990121, COSV62262398; called by muse, mutect2, varscan2
- ARFGAP3 | c.896del p.N299Mfs*22 | Frame Shift Del (DEL) | VAF 40/85 reads (47%) | catalogued as rs774441374, COSV54310368; called by mutect2, varscan2
- ARHGAP10 | c.1574A>G p.K525R | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.147); catalogued as COSV100330728; called by muse, mutect2, varscan2
- ARHGAP30 | c.1764C>A p.C588* | Nonsense Mutation (SNP) | VAF 25/91 reads (27%) | catalogued as COSV100920084, COSV63515732; called by muse, mutect2, varscan2
- ARHGAP9 | c.1504C>T p.R502W (on ENST00000393797 / NM_001319850.2; = p.R483W on NM_032496.4) | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV99953631; called by muse, mutect2
- ARHGAP9 | c.4C>A p.L2I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.097); catalogued as COSV100712318; called by muse, mutect2, varscan2
- ARHGEF18 | c.1780C>T p.Q594* (on ENST00000359920 / NM_001130955.2; = p.Q490* on NM_015318.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 39/84 reads (46%) | catalogued as COSV100148821; called by muse, mutect2, varscan2
- ARID1A | c.1712C>T p.S571L | Missense Mutation (SNP) | VAF 74/227 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.057); catalogued as rs969170076, COSV61388612; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 22/67 reads (33%) | catalogued as COSV61389445; called by mutect2, pindel, varscan2
- ARL6IP5 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as rs755128182, COSV99832886; called by muse, mutect2, varscan2
- ARMC4 | c.2515G>T p.G839* | Nonsense Mutation (SNP) | VAF 20/61 reads (33%) | catalogued as COSV100536026; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 22/32 reads (69%) | catalogued as rs753865255; called by mutect2, varscan2
- ASB10 | c.628C>T p.R210W (on ENST00000420175 / NM_001142459.2; = p.R195W on NM_080871.4) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs151344613, COSV51995846; called by muse, mutect2, varscan2
- ASB2 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs200689971, COSV60112158, COSV60114316; called by muse, mutect2, varscan2
- ASPM | c.8227C>T p.R2743* | Nonsense Mutation (SNP) | VAF 19/60 reads (32%) | catalogued as rs774702591, CM1415104, COSV99659160; called by muse, mutect2, varscan2
- ATF1 | c.140G>C p.S47T | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.973); catalogued as COSV100015927; called by muse, mutect2, varscan2
- ATF5 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs754317786, COSV100351685; called by muse, mutect2, varscan2
- ATL3 | c.959del p.G320Dfs*34 | Frame Shift Del (DEL) | VAF 36/94 reads (38%) | catalogued as COSV60295736; called by mutect2, pindel, varscan2
- ATP1A1 | c.2254G>A p.D752N | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV99814012; called by muse, mutect2, varscan2
- ATP2B1 | c.2075A>G p.D692G | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.053); catalogued as COSV99665023; called by muse, varscan2
- ATP4A | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1282429868, COSV99381931; called by muse, mutect2
- ATP6V0A4 | c.2000G>A p.R667Q | Missense Mutation (SNP) | VAF 59/175 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs759959455, COSV59473910; called by muse, mutect2, varscan2
- ATP7B | c.3619C>T p.H1207Y | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.57); PolyPhen benign (0.02); catalogued as rs766820841, COSV54436795, COSV99665903; called by muse, mutect2, varscan2
- AZIN2 | c.458T>C p.V153A | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as rs1161027683, COSV99612793; called by muse, mutect2, varscan2
- B3GALT4 | c.406G>T p.G136W | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101005531; called by muse, mutect2, varscan2
- B4GALNT2 | c.758A>C p.K253T | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.69); catalogued as COSV100302305; called by muse, mutect2, varscan2
- BAG5 | c.974dup p.N325Kfs*23 | Frame Shift Ins (INS) | VAF 25/64 reads (39%) | catalogued as rs1002009532; called by mutect2, varscan2
- BAZ2A | c.5150A>G p.D1717G | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99464240; called by muse, mutect2, varscan2
- BCAS1 | c.1509G>T p.K503N | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101005940; called by muse, mutect2, varscan2
- BCKDK | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs761345355, COSV99570355; called by muse, mutect2, varscan2
- BCL2 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs772554403, COSV61379907; called by muse, mutect2, varscan2
- BCOR | c.3621del p.K1207Nfs*31 (on ENST00000378444 / NM_001123385.2; = p.K1173Nfs*31 on NM_017745.6) | Frame Shift Del (DEL) | VAF 39/65 reads (60%) | catalogued as CD0910695, COSV60699328; called by mutect2, pindel, varscan2
- BDKRB1 | c.82A>C p.N28H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV99387667; called by muse, mutect2, varscan2
- BDNF | c.620A>C p.Q207P | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100150962; called by muse, mutect2, varscan2
- BDP1 | c.938dup p.L313Ffs*9 | Frame Shift Ins (INS) | VAF 15/37 reads (41%) | catalogued as rs752427670; called by mutect2, varscan2
- BICD1 | c.746G>A p.R249Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as rs1264580521, COSV99861797; called by muse, mutect2, varscan2
- BMPR1A | c.752G>A p.G251D | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1554890768, COSV100923208; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BNC1 | c.1940G>T p.R647M | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.188); catalogued as COSV100596776; called by muse, mutect2, varscan2
- BNC1 | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61758502; called by muse, mutect2, varscan2
- BOC | c.2546G>A p.R849H | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs571119647, COSV99847751; called by muse, mutect2, varscan2
- BPIFB4 | c.536C>A p.A179E | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100971373, COSV64951459; called by muse, mutect2, varscan2
- BRCA2 | c.6605A>G p.D2202G | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.228); catalogued as COSV101203789; called by muse, mutect2, varscan2
- BRICD5 | c.112C>G p.L38V | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.656); catalogued as COSV100062967; called by muse, varscan2
- BRSK1 | c.1135del p.R379Gfs*9 | Frame Shift Del (DEL) | VAF 19/46 reads (41%) | catalogued as rs746043904, COSV58665984; called by mutect2, varscan2
- BSN | c.11194C>G p.P3732A | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV99606830; called by muse, mutect2, varscan2
- BTBD11 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99774394; called by muse, mutect2, varscan2
- BTBD7 | c.3003dup p.Q1002Tfs*5 | Frame Shift Ins (INS) | VAF 44/144 reads (31%) | catalogued as rs762347380; called by mutect2, pindel, varscan2
- BTBD7 | c.173del p.K58Rfs*44 | Frame Shift Del (DEL) | VAF 42/116 reads (36%) | catalogued as rs752512017; called by mutect2, varscan2
- BTRC | c.1528C>T p.R510C (on ENST00000370187 / NM_033637.4; = p.R474C on NM_003939.5) | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64579491; called by muse, mutect2, varscan2
- C11orf49 | c.368T>A p.I123N | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99561425; called by muse, mutect2, varscan2
- C11orf87 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.088); catalogued as COSV100535613; called by muse, mutect2, varscan2
- C1S | c.842del p.K281Rfs*39 | Frame Shift Del (DEL) | VAF 31/103 reads (30%) | catalogued as rs781818365; called by mutect2, pindel, varscan2
- C4BPB | c.10dup p.W4Lfs*29 | Frame Shift Ins (INS) | VAF 12/38 reads (32%) | catalogued as rs1558074374; called by mutect2, varscan2
- CABIN1 | c.5018G>A p.R1673H | Missense Mutation (SNP) | VAF 30/223 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs375275130, COSV54086026; called by muse, mutect2, varscan2
- CACNA1A | c.3603del p.E1202Rfs*43 | Frame Shift Del (DEL) | VAF 11/54 reads (20%) | catalogued as rs747879307; called by mutect2, pindel, varscan2
- CACNA1C | c.6565C>T p.R2189C (on ENST00000399634 / NM_001167625.1; = p.R2118C on NM_000719.7) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs769552189, COSV59703256; called by muse, mutect2, varscan2
- CACNA1H | c.6570del p.C2191Afs*26 | Frame Shift Del (DEL) | VAF 39/69 reads (57%) | catalogued as rs760298114; called by mutect2, pindel, varscan2
- CACNG6 | c.626del p.P209Rfs*21 (on ENST00000252729 / NM_145814.1; = p.P138Rfs*21 on NM_031897.2) | Frame Shift Del (DEL) | VAF 31/84 reads (37%) | catalogued as rs745648688, COSV53168096; called by mutect2, pindel, varscan2
- CADM1 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.364); catalogued as rs1053413125, COSV59014747; called by muse, mutect2, varscan2
- CADPS2 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.857); catalogued as rs756409034, COSV100460109; called by muse, mutect2, varscan2
- CAMSAP1 | c.3962G>A p.R1321H | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100409468, COSV56728851; called by muse, mutect2, varscan2
- CARMIL3 | c.2190G>T p.A730= | Splice Region (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100549013, COSV57727570; called by muse, mutect2, varscan2
- CASP1 | c.614del p.N205Ifs*7 (on ENST00000436863 / NM_033292.4; = p.N184Ifs*7 on NM_001223.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 28/89 reads (31%) | catalogued as rs746543598, COSV62056860; called by mutect2, varscan2
- CASP8AP2 | c.4421G>A p.S1474N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.957); catalogued as COSV99386664; called by muse, mutect2, varscan2
- CBFA2T3 | c.285del p.S96Pfs*24 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | catalogued as rs746278669; called by mutect2, pindel, varscan2
- CBY2 | c.421C>T p.R141C | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as rs1480608165, COSV100137357; called by muse, mutect2, varscan2
- CC2D2A | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.015); catalogued as COSV101052610; called by muse, mutect2, varscan2
- CCDC172 | c.214C>T p.H72Y | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.241); catalogued as COSV100319599; called by muse, mutect2, varscan2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCDC73 | c.2288G>A p.C763Y | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.96); PolyPhen benign (0.018); catalogued as rs746170374, COSV100066006; called by muse, mutect2, varscan2
- CCDC73 | c.1913del p.N638Ifs*18 | Frame Shift Del (DEL) | VAF 26/60 reads (43%) | catalogued as rs762553129; called by mutect2, varscan2
- CCER1 | c.1151del p.L384* | Frame Shift Del (DEL) | VAF 19/77 reads (25%) | catalogued as rs1565866062; called by mutect2, pindel, varscan2
- CCN6 | c.624del p.K208Nfs*24 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | catalogued as rs781790231; called by mutect2, varscan2
- CCR7 | c.95A>G p.Y32C | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV99878522; called by muse, mutect2, varscan2
- CCSER2 | c.338G>T p.G113V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs1433556123, COSV99825287; called by muse, mutect2, varscan2
- CD300C | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1208412397, COSV100423136; called by muse, mutect2, varscan2
- CD33 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.797); catalogued as COSV99219936; called by muse, mutect2, varscan2
- CD38 | c.666del p.F222Lfs*17 | Frame Shift Del (DEL) | VAF 38/113 reads (34%) | catalogued as COSV56892082; called by mutect2, pindel, varscan2
- CD3D | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as COSV99416367; called by muse, mutect2, varscan2
- CD59 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV100681092; called by muse, mutect2, varscan2
- CD70 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.025); catalogued as rs534715855, COSV99835474; called by muse, mutect2, varscan2
- CD82 | c.620A>G p.E207G | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.173); catalogued as COSV99907315; called by muse, mutect2, varscan2
- CDC42BPB | c.2494C>T p.R832W | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760767641, COSV63474415; called by muse, mutect2, varscan2
- CDH24 | c.2135del p.P712Rfs*129 | Frame Shift Del (DEL) | VAF 13/59 reads (22%) | catalogued as rs752398646; called by mutect2, pindel
- CDH26 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 76/220 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99721494; called by muse, mutect2, varscan2
- CDH4 | c.2326G>A p.V776I | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.859); catalogued as rs142330895; called by muse, mutect2, varscan2
- CDHR2 | c.2363del p.G788Vfs*4 | Frame Shift Del (DEL) | VAF 33/121 reads (27%) | catalogued as rs868286996; called by mutect2, pindel, varscan2
- CDK11A | c.1718G>A p.R573Q (on ENST00000378633 / NM_001313896.2; = p.R570Q on NM_024011.4) | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs372661453; called by muse, varscan2
- CDK17 | c.59A>C p.E20A | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.114); catalogued as COSV54127264; called by muse, mutect2, varscan2
- CDKL1 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99367133; called by muse, mutect2, varscan2
- CDKL2 | c.222del p.K74Nfs*5 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | catalogued as rs753353408; called by mutect2, varscan2
- CDKL5 | c.2911G>A p.G971S | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); catalogued as COSV101183672; called by muse, mutect2, varscan2
- CDS2 | c.1283T>C p.L428P | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100986043; called by muse, mutect2, varscan2
- CELF6 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.78); PolyPhen benign (0.067); catalogued as rs776086543, COSV54715430; called by muse, mutect2, varscan2
- CEMIP2 | c.642G>A p.M214I | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1422668681, COSV100987181; called by muse, mutect2, varscan2
- CEP250 | c.4202G>T p.R1401I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100698664; called by muse, mutect2, varscan2
- CEP85 | c.1427T>A p.I476N | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV99431508; called by muse, mutect2, varscan2
- CEP89 | c.2198G>A p.R733Q | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as rs141423846; called by muse, mutect2, varscan2
- CES4A | c.518G>A p.G173D | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100109857; called by muse, mutect2, varscan2
- CFAP74 | c.1607del p.K536Rfs*5 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs747008990; called by mutect2, pindel, varscan2
- CFHR5 | c.1303C>T p.R435* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as rs758392186, COSV56821201; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CH25H | c.757T>C p.Y253H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.076); catalogued as COSV100897323; called by muse, mutect2, varscan2
- CHDH | c.944A>G p.D315G | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.524); catalogued as COSV100179461; called by muse, mutect2, varscan2
- CHSY1 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs74040399; called by muse, mutect2, varscan2
- CILP | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs776344445, COSV99972606; called by muse, mutect2, varscan2
- CIT | c.4724A>G p.D1575G | Missense Mutation (SNP) | VAF 117/267 reads (44%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.989); catalogued as COSV99947958, COSV99950258; called by muse, mutect2, varscan2
- CKAP4 | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.777); catalogued as COSV100952365; called by muse, mutect2, varscan2
- CLASRP | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); catalogued as rs752674221, COSV99673368; called by muse, mutect2, varscan2
- CLASRP | c.2003G>A p.R668Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as rs755598805, COSV55516552; called by muse, mutect2, varscan2
- CLEC16A | c.3145G>T p.G1049C | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as COSV99901153; called by muse, mutect2, varscan2
- CLEC1B | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 96/291 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1237872141, COSV53725393, COSV53726050; called by muse, mutect2, varscan2
- CLEC1B | c.95T>C p.V32A | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.237); catalogued as COSV100045860; called by muse, mutect2, varscan2
- CLIP3 | c.400G>A p.G134R | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100859216; called by muse, mutect2, varscan2
- CLN3 | c.445A>G p.T149A (on ENST00000360019 / NM_001286104.2; = p.T173A on NM_000086.2) | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.869); catalogued as COSV100342930; called by muse, mutect2
- CLUH | c.740G>T p.R247L (on ENST00000435359; = p.R285L on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV101425579; called by muse, mutect2, varscan2
- CLUH | c.333G>T p.Q111H (on ENST00000435359; = p.Q149H on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.289); catalogued as COSV101425583; called by muse, mutect2, varscan2
- CMKLR1 | c.647G>A p.R216Q (on ENST00000312143 / NM_001142344.2; = p.R214Q on NM_004072.3) | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs1216082084, COSV100379114, COSV56439069; called by muse, mutect2, varscan2
- CNGB1 | c.3062C>T p.T1021M | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as rs774186674, COSV51898360; called by muse, mutect2, varscan2
- CNNM2 | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV100881612; called by muse, mutect2, varscan2
- CNRIP1 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as rs774606543, COSV99721051; called by muse, mutect2, varscan2
- CNTD1 | c.950T>C p.L317P | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV100162005; called by muse, mutect2, varscan2
- CNTN3 | c.2266C>A p.P756T | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV99722803; called by muse, mutect2, varscan2
- CNTN3 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV55162822; called by muse, mutect2, varscan2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 25/85 reads (29%) | catalogued as rs758676375; called by mutect2, varscan2
- CNTNAP2 | c.2948G>T p.R983I | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV100661404; called by muse, mutect2, varscan2
- CNTNAP4 | c.3530C>T p.A1177V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV100268832; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 24/44 reads (55%) | catalogued as rs374805044; called by mutect2, varscan2
- COG2 | c.380del p.K127Rfs*5 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs1188081815, COSV100794718; called by mutect2, varscan2
- COG6 | c.557T>C p.L186P | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100742522; called by muse, mutect2, varscan2
- COIL | c.587del p.K196Rfs*13 | Frame Shift Del (DEL) | VAF 96/129 reads (74%) | catalogued as rs748995811; called by mutect2, varscan2
- COL16A1 | c.4024G>A p.E1342K | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs755234349, COSV99593200; called by muse, mutect2, varscan2
- COL19A1 | c.92-1G>T p.X31_splice | Splice Site (SNP) | VAF 15/38 reads (39%) | catalogued as COSV100504706; called by muse, mutect2, varscan2
- COL4A1 | c.4942T>G p.S1648A | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.316); catalogued as rs745486159, COSV101010895; called by muse, mutect2
- COL5A2 | c.3856G>A p.D1286N | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1194645204, COSV100879857; called by muse, mutect2, varscan2
- COL5A2 | c.2725G>T p.G909* | Nonsense Mutation (SNP) | VAF 30/66 reads (45%) | catalogued as COSV100879858; called by muse, mutect2, varscan2
- COL8A2 | c.684del p.G229Afs*8 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs769991029; called by mutect2, varscan2
- COLQ | c.595G>T p.E199* | Nonsense Mutation (SNP) | VAF 45/134 reads (34%) | catalogued as COSV101081914; called by muse, mutect2, varscan2
- CPA6 | c.49C>A p.L17I | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV99911869; called by muse, mutect2, varscan2
- CPS1 | c.2762T>G p.L921R | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV99241258; called by muse, mutect2, varscan2
- CPSF2 | c.1654del p.I552Sfs*5 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | catalogued as rs758712860; called by mutect2, pindel, varscan2
- CPZ | c.1496T>C p.V499A (on ENST00000360986 / NM_001014447.3; = p.V488A on NM_003652.3) | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV100248644; called by muse, mutect2, varscan2
- CR1 | c.3379G>A p.G1127S | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs749316044, COSV100887273; called by muse, mutect2, varscan2
- CRY1 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as rs200714794, COSV99150263; called by muse, mutect2, varscan2
- CSF2RA | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs749182596, COSV62624548; called by muse, mutect2, varscan2
- CSMD1 | c.5293C>T p.R1765* (on ENST00000520002; = p.R1764* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as COSV59298786; called by muse, mutect2
- CSMD2 | c.2197G>A p.V733I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs779556893, COSV53907596, COSV53925434; called by muse, mutect2, varscan2
- CTNNA3 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs769674937, COSV65597724; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYFIP2 | c.408C>A p.F136L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV100555285; called by muse, mutect2
- CYP11B2 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV100010454; called by muse, mutect2, varscan2
- CYP21A2 | c.376T>G p.S126A | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.927); catalogued as COSV100925659; called by muse, mutect2, varscan2
- CYP21A2 | c.1066C>A p.L356M | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); catalogued as COSV100925660; called by muse, varscan2
- CYP26A1 | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99814476; called by muse, mutect2, varscan2
- CYP2A6 | c.902G>C p.G301A | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs60823196, COSV99991674; called by mutect2, varscan2
- CYTIP | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs756398323, COSV99938588, COSV99938736; called by muse, mutect2, varscan2
- DAB2IP | c.2357C>T p.P786L (on ENST00000408936; = p.P758L on NM_032552.3) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs780248582, COSV52256884; called by muse, mutect2, varscan2
- DACT1 | c.2140G>A p.A714T | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV60019545, COSV60022757; called by muse, mutect2, varscan2
- DBNDD2 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61918610; called by muse, mutect2, varscan2
- DCD | c.236del p.G79Dfs*5 | Frame Shift Del (DEL) | VAF 36/111 reads (32%) | catalogued as rs758489970; called by mutect2, pindel, varscan2
- DCLK2 | c.1352A>C p.N451T | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99651037; called by muse, mutect2, varscan2
- DCLRE1A | c.1471A>G p.S491G | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100800117; called by muse, mutect2, varscan2
- DCSTAMP | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138578884; called by muse, mutect2, varscan2
- DDX17 | c.2110A>G p.T704A | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV99317966; called by muse, mutect2, varscan2
- DDX17 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.934); catalogued as rs749692045, COSV99317967; called by muse, mutect2, varscan2
- DDX50 | c.2086C>T p.R696* | Nonsense Mutation (SNP) | VAF 22/55 reads (40%) | catalogued as rs143037779; called by muse, mutect2, varscan2
- DDX54 | c.1273C>T p.R425C | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753775513, COSV100013495, COSV58373765; called by muse, mutect2
- DENND3 | c.290C>T p.T97M | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.35); catalogued as rs559179440, COSV52802702; called by muse, mutect2, varscan2
- DGKG | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.103); catalogued as COSV99402038; called by muse, mutect2, varscan2
- DGKQ | c.2050C>T p.R684* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | catalogued as rs1303880380, COSV99297412; called by muse, mutect2, varscan2
- DHRS1 | c.196A>C p.S66R | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV99852090; called by muse, mutect2, varscan2
- DIS3L2 | c.1882A>G p.M628V | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV99804892; called by muse, mutect2, varscan2
- DISC1 | c.2202del p.R735Gfs*12 | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | catalogued as COSV100790088; called by mutect2, pindel, varscan2
- DLAT | c.723del p.V242Wfs*5 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs782029228, COSV54771743; called by mutect2, varscan2
- DLD | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99226675; called by muse, mutect2, varscan2
- DLG4 | c.1639G>A p.A547T (on ENST00000399506 / NM_001321075.3; = p.A590T on NM_001365.4) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs760656143, COSV57237244; called by muse, mutect2, varscan2
- DLG5 | c.5141G>A p.S1714N | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100967158; called by muse, mutect2, varscan2
- DLL4 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 78/186 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99989515; called by muse, mutect2, varscan2
- DLX6 | c.804dup p.N269Qfs*59 | Frame Shift Ins (INS) | VAF 10/24 reads (42%) | catalogued as rs1469158094; called by mutect2, pindel, varscan2
- DNAH10 | c.10213C>T p.R3405W (on ENST00000409039; = p.R3344W on NM_207437.3) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs200075659, COSV68995201; called by muse, mutect2, varscan2
- DNAH12 | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1336353926, COSV100244248; called by muse, mutect2, varscan2
- DNAH7 | c.1037del p.K346Sfs*23 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | catalogued as rs761292636; called by mutect2, varscan2
- DNAH9 | c.9617G>A p.R3206Q | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs758199662, COSV52357604; called by muse, mutect2, varscan2
- DNMT1 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs759600542, COSV100531487; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK8 | c.3339dup p.M1114Yfs*4 | Frame Shift Ins (INS) | VAF 14/38 reads (37%) | catalogued as rs748134881; called by mutect2, varscan2
- DPF2 | c.430G>T p.G144C | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.174); catalogued as rs755588550, COSV99361237; called by muse, mutect2, varscan2
- DPP10 | c.749G>A p.R250K | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100056193; called by muse, mutect2, varscan2
- DPP9 | c.398G>A p.R133H (on ENST00000598800; = p.R162H on NM_139159.5) | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99505554; called by muse, mutect2, varscan2
- DRD3 | c.725C>T p.T242I | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as COSV99879036; called by muse, mutect2, varscan2
- DSCAML1 | c.1491del p.T498Rfs*33 (on ENST00000321322; = p.T438Rfs*33 on NM_020693.4) | Frame Shift Del (DEL) | VAF 25/63 reads (40%) | catalogued as COSV58386901; called by mutect2, pindel, varscan2
- DYNC1H1 | c.6865G>A p.D2289N | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV100794131; called by muse, mutect2, varscan2
- DYRK4 | c.1063del p.R355Dfs*12 | Frame Shift Del (DEL) | VAF 25/81 reads (31%) | catalogued as rs768937539; called by mutect2, pindel, varscan2
- EAPP | c.374dup p.K126Efs*10 | Frame Shift Ins (INS) | VAF 21/59 reads (36%) | catalogued as rs1257825851; called by mutect2, varscan2
- EDC4 | c.2177G>A p.R726H | Missense Mutation (SNP) | VAF 79/193 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs151306360, COSV100197361; called by muse, mutect2, varscan2
- EDIL3 | c.308A>G p.Y103C | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99673597; called by muse, mutect2, varscan2
- EFEMP2 | c.397G>T p.D133Y | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs766172211, COSV100337127; called by muse, mutect2
- EFS | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.168); catalogued as rs373976977, COSV53734153; called by muse, mutect2, varscan2
- EHBP1L1 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV100499538; called by muse, mutect2, varscan2
- EHBP1L1 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100499539; called by muse, mutect2, varscan2
- EHD2 | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as rs1229924208, COSV99621433; called by muse, mutect2, varscan2
- EIF4G1 | c.2636G>A p.R879H (on ENST00000346169 / NM_198241.3; = p.R684H on NM_004953.5) | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); catalogued as rs1199797589, COSV59994054; called by muse, mutect2, varscan2
- ELMO3 | c.1248del p.G417Vfs*44 (on ENST00000652269; = p.G364Vfs*44 on NM_024712.5) | Frame Shift Del (DEL) | VAF 23/84 reads (27%) | catalogued as rs781430251; called by mutect2, pindel, varscan2
- ELOA2 | c.2051C>T p.T684I | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs774047592, COSV99795629; called by muse, mutect2, varscan2
- ELOVL1 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100196245; called by muse, mutect2, varscan2
- ENTPD1 | c.10A>G p.T4A | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.005); catalogued as rs867832250, COSV101496520; called by muse, mutect2, varscan2
- EP400 | c.1630G>A p.V544M | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs190189185, COSV100199972; called by muse, mutect2, varscan2
- EPG5 | c.6791T>C p.M2264T | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.461); catalogued as rs1181457009, COSV99956185; called by muse, mutect2, varscan2
- EPHA4 | c.2918G>A p.R973Q | Missense Mutation (SNP) | VAF 66/177 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs140023331; called by muse, mutect2, varscan2
- EPHA5 | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.935); catalogued as COSV99894827; called by muse, mutect2, varscan2
- EPHA7 | c.2032G>A p.D678N | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs1256527658, COSV65191152, COSV65194854; called by muse, mutect2, varscan2
- EPHB2 | c.704T>C p.V235A | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.998); catalogued as COSV65864533; called by muse, mutect2, varscan2
- EPHX2 | c.842T>C p.L281P | Missense Mutation (SNP) | VAF 76/273 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV100994433, COSV66845288; called by muse, mutect2, varscan2
- ERBB3 | c.1748C>T p.P583L | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV57246901; called by muse, mutect2, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 17/56 reads (30%) | catalogued as rs753821453; called by mutect2, varscan2
- ERP44 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99315913; called by muse, mutect2, varscan2
- ESYT3 | c.600G>T p.E200D | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.787); catalogued as COSV100004697; called by muse, mutect2, varscan2
- EVI2B | c.593del p.N198Tfs*6 | Frame Shift Del (DEL) | VAF 25/83 reads (30%) | catalogued as rs765136869; called by mutect2, pindel, varscan2
- EXO5 | c.842T>G p.L281R | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.603); catalogued as COSV99591145; called by muse, mutect2, varscan2
- F13B | c.1778A>T p.N593I | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV100803123, COSV66375313; called by muse, varscan2
- F2RL1 | c.83-1G>T p.X28_splice | Splice Site (SNP) | VAF 24/74 reads (32%) | catalogued as COSV99688600; called by muse, mutect2, varscan2
- F5 | c.4611C>A p.D1537E | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as rs770480723, COSV63128634; called by muse, mutect2, varscan2
- FAM104A | c.9dup p.R4Afs*8 | Frame Shift Ins (INS) | VAF 7/34 reads (21%) | catalogued as rs770000277; called by mutect2, varscan2
- FAM117A | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs753106696, COSV99544343; called by muse, mutect2, varscan2
- FAM161A | c.1645T>A p.L549I | Missense Mutation (SNP) | VAF 75/188 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs1553353341, COSV100281040; called by muse, varscan2
- FAM187B | c.434G>A p.W145* | Nonsense Mutation (SNP) | VAF 25/71 reads (35%) | catalogued as COSV100219902; called by muse, mutect2, varscan2
- FAM71A | c.1115T>C p.I372T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV99674244; called by muse, mutect2, varscan2
- FAM83H | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1554624021, COSV66353877, COSV66354673; called by muse, mutect2, varscan2
- FAT1 | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs376051210; called by muse, mutect2, varscan2
- FAT2 | c.8797G>A p.A2933T | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.26); catalogued as rs778219876, COSV99941220; called by muse, mutect2, varscan2
- FAT4 | c.9695C>T p.A3232V | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs373873722; called by muse, mutect2, varscan2
- FAT4 | c.11048T>C p.L3683P | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100626779; called by muse, mutect2, varscan2
- FAT4 | c.12701G>A p.S4234N | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs1172646458, COSV100626781; called by muse, mutect2, varscan2
- FBXL6 | c.1498C>A p.L500M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100095377; called by muse, mutect2, varscan2
- FBXO11 | c.1568A>G p.N523S (on ENST00000403359 / NM_001190274.2; = p.N439S on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV100318834; called by muse, mutect2, varscan2
- FBXO22 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs757686717, COSV57617254; called by muse, varscan2
- FBXO25 | c.199del p.R67Gfs*44 (on ENST00000382824 / NM_183421.2; = p.G17Efs*6 on NM_012173.3) | Frame Shift Del (DEL) | VAF 25/91 reads (27%) | catalogued as rs758426962; called by mutect2, pindel, varscan2
- FCRLA | c.16A>T p.S6C | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV99375560; called by muse, mutect2, varscan2
- FERMT2 | c.168del p.D57Ifs*17 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | catalogued as rs1225761410; called by mutect2, pindel, varscan2
- FES | c.808T>C p.S270P | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV100182518; called by muse, mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 26/78 reads (33%) | catalogued as rs748969702; called by mutect2, varscan2
- FEZ1 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV99630095; called by muse, mutect2, varscan2
- FGD3 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779311657, COSV61596043; called by muse, mutect2, varscan2
- FGD6 | c.4231G>T p.A1411S | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100676279; called by muse, mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 23/82 reads (28%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FIZ1 | c.692C>A p.P231Q | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.597); catalogued as COSV99684385; called by muse, mutect2
- FMNL3 | c.887T>C p.V296A | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV99525418; called by muse, varscan2
- FOXP2 | c.1921G>A p.V641I | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs745987986, COSV63484878; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1949C>T p.A650V | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV100435045; called by muse, mutect2, varscan2
- FRMPD2 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs372356208; called by muse, mutect2, varscan2
- FSCB | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 34/113 reads (30%) | catalogued as COSV100468691; called by muse, mutect2, varscan2
- FSCN2 | c.1181G>A p.C394Y | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.944); catalogued as COSV100585140; called by muse, mutect2, varscan2
- FSD2 | c.349C>A p.Q117K | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV100574948; called by muse, mutect2, varscan2
- FSIP1 | c.1318G>A p.V440M | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100617904; called by muse, mutect2, varscan2
- FTH1 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV99861129; called by muse, mutect2, varscan2
- GABRR2 | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768368381, COSV68764572; called by muse, mutect2, varscan2
- GALNT1 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.088); catalogued as COSV52454768, COSV99321734; called by mutect2, varscan2
- GALNT5 | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763670213, COSV99374706; called by muse, mutect2, varscan2
- GALR2 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.107); catalogued as rs759763601, COSV57162070; called by muse, mutect2, varscan2
- GAN | c.1466C>T p.T489I | Missense Mutation (SNP) | VAF 69/149 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.351); catalogued as COSV101633947; called by muse, mutect2, varscan2
- GAPVD1 | c.2942G>A p.R981H (on ENST00000394104; = p.R1008H on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as rs757442949, COSV99782432; called by muse, mutect2, varscan2
- GARS1 | c.1940T>C p.V647A | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs1191900293, COSV101219848; called by muse, mutect2, varscan2
- GART | c.2420del p.K807Rfs*7 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs758551787; called by mutect2, varscan2
- GBA | c.1474G>A p.D492N | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs779958429, COSV100516153; called by muse, mutect2, varscan2
- GBA | c.203del p.P68Rfs*23 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | catalogued as CD941682; called by mutect2, pindel, varscan2
- GBF1 | c.5059A>G p.S1687G (on ENST00000369983 / NM_001377137.1; = p.S1686G on NM_004193.3) | Missense Mutation (SNP) | VAF 98/275 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs1469993493, COSV100890219; called by muse, mutect2, varscan2
- GCC2 | c.4333G>T p.D1445Y | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV100565139; called by muse, mutect2, varscan2
- GCK | c.623C>T p.A208V | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746913146, CM096852, COSV100356937; ClinVar: uncertain significance; called by muse, varscan2
- GDPD5 | c.1474-1G>A p.X492_splice | Splice Site (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100408936; called by muse, mutect2, varscan2
- GINS1 | c.71T>A p.F24Y | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV99319875; called by muse, mutect2, varscan2
- GJB1 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs144381053, CM973186, COSV100661221; called by muse, varscan2
- GLI3 | c.2990C>T p.A997V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV67886636; called by muse, mutect2, varscan2
- GLI3 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs555794809, COSV67889346; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GML | c.4C>A p.L2I | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as COSV55276449, COSV99638009; called by muse, mutect2, varscan2
- GNL3 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV66920946; called by muse, mutect2, varscan2
- GOLGA3 | c.1909C>T p.R637C | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372097416; called by muse, mutect2, varscan2
- GPAA1 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs973868750, COSV100283930, COSV60155407; called by muse, mutect2, varscan2
- GPATCH2L | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.049); catalogued as rs754589263, COSV99833282; called by muse, mutect2, varscan2
- GPC5 | c.164-1G>T p.X55_splice | Splice Site (SNP) | VAF 20/61 reads (33%) | catalogued as COSV100992276; called by muse, mutect2, varscan2
- GPR101 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 35/49 reads (71%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1216767274, COSV53237457; called by muse, mutect2, varscan2
- GPR135 | c.883T>G p.F295V | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.453); catalogued as COSV101229274; called by muse, mutect2, varscan2
- GPR153 | c.397G>T p.G133C | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100928420; called by muse, varscan2
- GPR162 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1565507618, COSV99163675; called by muse, mutect2, varscan2
- GPR19 | c.1109del p.N370Tfs*59 | Frame Shift Del (DEL) | VAF 50/116 reads (43%) | catalogued as rs1416935976; called by mutect2, varscan2
- GPR26 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as COSV99500690; called by muse, varscan2
- GPR84 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs140774381, COSV57210301; called by muse, mutect2, varscan2
- GREB1 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as rs768624823, COSV52192898; called by muse, mutect2, varscan2
- GREB1 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs371122998; called by muse, varscan2
- GREB1 | c.3689C>T p.S1230F | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); catalogued as rs1402515469, COSV99301950; called by muse, mutect2, varscan2
- GRN | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV99274441; called by muse, mutect2, varscan2
- GSE1 | c.3431G>T p.R1144L | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53675734, COSV99495854; called by muse, mutect2, varscan2
- GSTA4 | c.273-1G>T p.X91_splice | Splice Site (SNP) | VAF 26/74 reads (35%) | catalogued as COSV100919763; called by muse, varscan2
- GSTT2B | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1482985302; called by mutect2, varscan2
- GTSF1L | c.363del p.P122Lfs*50 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | catalogued as rs1568892529; called by mutect2, pindel, varscan2
- GUF1 | c.1934del p.K645Sfs*2 | Frame Shift Del (DEL) | VAF 21/57 reads (37%) | catalogued as COSV54945907; called by mutect2, varscan2
- HAP1 | c.1279G>A p.V427M | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs782107429, COSV57878566; called by muse, mutect2, varscan2
- HASPIN | c.19G>T p.G7* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as rs1328611436, COSV99560049; called by muse, mutect2, varscan2
- HCFC1 | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV100128188; called by muse, mutect2, varscan2
- HDAC4 | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs142554712; called by muse, mutect2, varscan2
- HDHD2 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs777943774, COSV56077193; called by muse, mutect2, varscan2
- HEATR3 | c.398A>G p.E133G | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV99589690; called by muse, mutect2, varscan2
- HECTD4 | c.13019G>A p.R4340H | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66386535; called by muse, mutect2, varscan2
- HECTD4 | c.3914G>A p.R1305H | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs370702531; called by muse, mutect2, varscan2
- HEG1 | c.4090G>A p.G1364R | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100229835, COSV60761255; called by muse, mutect2, varscan2
- HERC2 | c.6672G>A p.M2224I | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs758093331, COSV99869593; called by muse, mutect2, varscan2
- HIP1R | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs770982695, COSV99458020; called by muse, mutect2, varscan2
- HIPK2 | c.3349G>A p.V1117M | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.921); catalogued as rs751302512, COSV101301607; called by muse, mutect2, varscan2
- HIVEP2 | c.4880C>T p.T1627M | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs772827582, COSV99171392; called by muse, mutect2, varscan2
- HIVEP2 | c.4424C>A p.A1475D | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99171393; called by muse, mutect2, varscan2
- HIVEP3 | c.6166G>A p.E2056K | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs911204910, COSV99911021; called by muse, mutect2, varscan2
- HJURP | c.2114A>G p.D705G | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100982528; called by muse, mutect2, varscan2
- HJV | c.431C>T p.A144V (on ENST00000336751 / NM_213653.4; = p.A31V on NM_145277.5) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs937971318, COSV60951289; called by muse, mutect2, varscan2
- HLA-A | c.627dup p.K210Qfs*11 | Frame Shift Ins (INS) | VAF 10/96 reads (10%) | catalogued as rs199474609; called by mutect2, varscan2
- HLX | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs370407346; called by muse, mutect2, varscan2
- HNF4A | c.457A>G p.N153D | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1365082353, COSV100290905; called by muse, mutect2, varscan2
- HOMEZ | c.1127del p.L376Yfs*14 | Frame Shift Del (DEL) | VAF 19/52 reads (37%) | catalogued as rs755016625; called by mutect2, varscan2
- HOXD8 | c.329del p.P110Lfs*67 | Frame Shift Del (DEL) | VAF 29/78 reads (37%) | catalogued as rs770632206; called by mutect2, pindel, varscan2
- HPDL | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 7/11 reads (64%) | catalogued as rs1187782846, COSV100587856; called by muse, mutect2, varscan2
- HRNR | c.2638C>T p.R880C | Missense Mutation (SNP) | VAF 51/127 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs551059466, COSV100912675; called by muse, mutect2, varscan2
- HS3ST3B1 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.039); catalogued as rs1372604134, COSV100714409; called by muse, mutect2
- HSCB | c.241C>A p.R81S | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as COSV99319621; called by muse, mutect2, varscan2
- HTR4 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs186099216, COSV58806831; called by muse, mutect2, varscan2
- IAH1 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99432305; called by muse, mutect2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | catalogued as rs747841314; called by mutect2, varscan2
- ICAM5 | c.1721G>T p.R574M | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.34); catalogued as COSV99703004; called by muse, mutect2, varscan2
- ICE1 | c.3281T>C p.L1094S | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as COSV99663110; called by muse, mutect2, varscan2
- IFFO1 | c.1477C>T p.R493W (on ENST00000396840 / NM_001330324.2; = p.R496W on NM_080730.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748439001, COSV99975300; called by muse, mutect2, varscan2
- IFT122 | c.896del p.G299Vfs*71 (on ENST00000348417 / NM_052989.3; = p.G240Vfs*71 on NM_018262.4) | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | catalogued as rs778534085; called by mutect2, pindel, varscan2
- IFT20 | c.79A>G p.T27A | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99879990; called by muse, mutect2, varscan2
- IGF2BP3 | c.269C>A p.P90H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99324795; called by muse, mutect2, varscan2
- IGFBP5 | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.203); catalogued as rs758025420, COSV99288723, COSV99288994; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.349A>G p.R117G | Missense Mutation (SNP) | VAF 87/215 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs370992049; called by muse, mutect2, varscan2
- IGSF1 | c.2431T>C p.Y811H | Missense Mutation (SNP) | VAF 77/95 reads (81%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); catalogued as COSV100811733; called by muse, mutect2, varscan2
- IGSF9 | c.1042G>A p.A348T (on ENST00000368094 / NM_001135050.2; = p.A332T on NM_020789.4) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100829558; called by muse, mutect2
- IL16 | c.3419C>T p.T1140M (on ENST00000302987 / NM_172217.5; = p.T439M on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs373703375; called by muse, mutect2, varscan2
- IL1RL2 | c.1312A>G p.I438V | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.401); catalogued as rs755879922, COSV99960098; called by muse, mutect2, varscan2
- IL21R | c.785G>A p.R262K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV100559707; called by muse, mutect2
- IL4I1 | c.757C>A p.L253I | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.526); catalogued as COSV55578007; called by muse, mutect2, varscan2
- ILK | c.211del p.L71Cfs*26 | Frame Shift Del (DEL) | VAF 22/57 reads (39%) | catalogued as rs776120061, COSV54448886; ClinVar: uncertain significance; called by mutect2, varscan2
- INPP1 | c.337G>T p.G113C | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100487045; called by muse, mutect2
- INPP5J | c.2195T>C p.F732S (on ENST00000331075 / NM_001284285.2; = p.F364S on NM_001002837.2) | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99311177; called by muse, mutect2
- INSC | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.731); catalogued as rs768595761, COSV101088602, COSV65412520; called by muse, mutect2, varscan2
- INSM2 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1460490439, COSV99352656; called by muse, mutect2, varscan2
- INTS1 | c.5132G>A p.R1711Q | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs772375961, COSV101247256; called by muse, mutect2, varscan2
- INTS1 | c.3388C>T p.R1130C | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs200026887; called by muse, mutect2, varscan2
- INTS2 | c.2615del p.P872Hfs*2 | Frame Shift Del (DEL) | VAF 6/18 reads (33%) | catalogued as rs753355779, COSV52155455; called by mutect2, varscan2
- INTS6L | c.359del p.L120* | Frame Shift Del (DEL) | VAF 28/36 reads (78%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- INTU | c.1772del p.L591Cfs*2 | Frame Shift Del (DEL) | VAF 31/97 reads (32%) | catalogued as COSV58874688; called by mutect2, pindel, varscan2
- IPO13 | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.355); catalogued as COSV100960994; called by muse, mutect2, varscan2
- IRS1 | c.1791del p.H598Tfs*38 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as rs761880048; called by mutect2, varscan2
- ISG15 | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs139357483; called by muse, mutect2, varscan2
- ITFG2 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs554016203, COSV99957909; called by muse, mutect2, varscan2
- ITGB2 | c.1361C>T p.A454V (on ENST00000302347; = p.A430V on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs769736820, COSV56612390; called by muse, mutect2, varscan2
- ITSN1 | c.1193G>T p.R398L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.158); catalogued as rs533840234, COSV101180424, COSV66080890, COSV66083403; called by muse, varscan2
- ITSN1 | c.1980G>A p.W660* | Nonsense Mutation (SNP) | VAF 23/62 reads (37%) | catalogued as COSV101180425; called by muse, mutect2, varscan2
- JAKMIP3 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs199726287, COSV53829249; called by muse, mutect2, varscan2
- JMJD1C | c.6075dup p.E2026Rfs*8 | Frame Shift Ins (INS) | VAF 18/50 reads (36%) | catalogued as rs1226801045; called by mutect2, varscan2
- JUN | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.146); catalogued as rs748223511, COSV100973351; called by muse, mutect2, varscan2
- KAT6A | c.5932T>C p.Y1978H | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99704118; called by muse, mutect2, varscan2
- KBTBD4 | c.1328G>A p.C443Y | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100442789; called by muse, varscan2
- KCNB1 | c.2234C>T p.A745V | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV65567491; called by muse, mutect2, varscan2
- KCNK1 | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs377600307, COSV100785635, COSV100785812; called by muse, mutect2, varscan2
- KCNK13 | c.1171del p.V391Wfs*7 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as rs766469179, COSV56415804; called by mutect2, pindel, varscan2
- KCNN4 | c.212T>C p.L71S | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV53454518; called by muse, mutect2, varscan2
- KCNQ3 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as COSV66467031; called by muse, mutect2, varscan2
- KCNQ4 | c.2048C>T p.T683M | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV61275523; called by muse, mutect2, varscan2
- KCTD16 | c.1149del p.A384Lfs*20 | Frame Shift Del (DEL) | VAF 28/77 reads (36%) | catalogued as rs753765917, COSV72577101; called by mutect2, varscan2
- KCTD19 | c.2301dup p.V768Rfs*12 | Frame Shift Ins (INS) | VAF 11/46 reads (24%) | catalogued as rs759860142; called by mutect2, varscan2
- KCTD6 | c.436A>G p.T146A | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.009); catalogued as COSV100249927; called by muse, mutect2, varscan2
- KDM3A | c.1004A>G p.Q335R | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.968); catalogued as COSV100459810; called by muse, mutect2, varscan2
- KDM3B | c.2860C>T p.R954C | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs866179776, COSV58689822; called by muse, mutect2, varscan2
- KDM4D | c.278del p.K93Rfs*4 | Frame Shift Del (DEL) | VAF 23/62 reads (37%) | catalogued as rs142280183; called by mutect2, varscan2
- KDM5D | c.1736G>A p.C579Y | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV100522118; called by muse, mutect2, varscan2
- KIAA1109 | c.8945C>A p.A2982D | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV99145305; called by muse, mutect2, varscan2
- KIF13B | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763630388, COSV101580492; called by muse, mutect2, varscan2
- KIF26A | c.792dup p.V265Rfs*5 | Frame Shift Ins (INS) | VAF 11/25 reads (44%) | catalogued as rs1489615146; called by mutect2, varscan2
- KIFAP3 | c.1538C>A p.S513Y | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.378); catalogued as COSV100846635; called by muse, mutect2, varscan2
- KL | c.1694C>T p.T565I | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV101198929; called by muse, mutect2, varscan2
- KLHL12 | c.7G>T p.G3C | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.161); catalogued as COSV100935585; called by muse, mutect2, varscan2
- KLHL26 | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.673); catalogued as COSV99962908; called by muse, mutect2, varscan2
- KLHL32 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0.056); catalogued as COSV100987029; called by muse, mutect2, varscan2
- KMT2C | c.13971T>A p.Y4657* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | catalogued as COSV100064132; called by muse, mutect2, varscan2
- KMT2C | c.13488del p.F4496Lfs*21 | Frame Shift Del (DEL) | VAF 35/112 reads (31%) | catalogued as COSV51456416; called by mutect2, pindel, varscan2
- KRCC1 | c.547del p.S183Afs*7 | Frame Shift Del (DEL) | VAF 38/112 reads (34%) | catalogued as rs1326358542; called by mutect2, varscan2
- KRT15 | c.1041G>T p.E347D | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54180719; called by muse, mutect2, varscan2
- KRT16 | c.647T>C p.V216A | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100052731; called by muse, mutect2, varscan2
- KRTAP19-5 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.304); catalogued as rs370451401, COSV100478344; called by muse, mutect2, varscan2
- KTN1 | c.3149T>G p.L1050R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100618285; called by muse, mutect2, varscan2
- LAMA5 | c.1867T>C p.Y623H | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as rs1284877575, COSV99437220; called by muse, mutect2, varscan2
- LCOR | c.1832C>T p.T611M | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.063); catalogued as rs199578400, COSV99616403; called by muse, mutect2, varscan2
- LCT | c.1453C>T p.Q485* | Nonsense Mutation (SNP) | VAF 18/41 reads (44%) | catalogued as rs779838486, COSV99928200; called by muse, mutect2, varscan2
- LDHD | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 65/147 reads (44%) | catalogued as rs754523857, COSV100096497; called by muse, mutect2, varscan2
- LGI2 | c.1294C>A p.L432I | Missense Mutation (SNP) | VAF 85/259 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.679); catalogued as COSV101180714, COSV101180964; called by muse, mutect2, varscan2
- LIG1 | c.1879C>T p.R627W | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as rs762816837, COSV54390948; called by muse, mutect2, varscan2
- LIMK2 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs777847145, COSV59181520; called by muse, mutect2, varscan2
- LMAN1 | c.823-2del p.X275_splice | Splice Site (DEL) | VAF 42/116 reads (36%) | catalogued as rs765287063; called by mutect2, varscan2
- LPAR2 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs775564995, COSV101345474; called by muse, mutect2, varscan2
- LRBA | c.4834G>A p.A1612T | Missense Mutation (SNP) | VAF 87/257 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100840722; called by muse, mutect2, varscan2
- LRFN5 | c.124C>A p.L42I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53254669, COSV99981850; called by muse, mutect2, varscan2
- LRP11 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs374603588, COSV53333027; called by muse, mutect2, varscan2
- LRP12 | c.1234A>G p.M412V | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99406941; called by muse, mutect2, varscan2
- LRRC3 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs577675305, COSV99381653; called by muse, mutect2, varscan2
- LRRC37A2 | c.3877A>G p.K1293E | Missense Mutation (SNP) | VAF 33/235 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV100238544; called by muse, mutect2, varscan2
- LRRC37B | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100495899; called by muse, mutect2, varscan2
- LRRC3B | c.601del p.T201Lfs*17 | Frame Shift Del (DEL) | VAF 12/33 reads (36%) | catalogued as COSV67521526; called by mutect2, pindel, varscan2
- LRRC8E | c.457C>A p.L153M | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100142527; called by muse, mutect2, varscan2
- LRRK1 | c.2446C>T p.R816* | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | catalogued as rs766532218, COSV52610706; called by muse, mutect2, varscan2
- LRSAM1 | c.1480T>C p.S494P | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.073); catalogued as COSV100030941; called by muse, mutect2, varscan2
- LYST | c.9243A>T p.Q3081H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101087691; called by muse, mutect2, varscan2
- MACROD2 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs1239687533, COSV53977215; called by muse, mutect2, varscan2
- MAGEE2 | c.133del p.Q45Sfs*27 | Frame Shift Del (DEL) | VAF 18/29 reads (62%) | catalogued as rs1159257962; called by mutect2, pindel, varscan2
- MAK16 | c.670G>T p.G224C | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.051); catalogued as COSV100659570; called by muse, mutect2, varscan2
- MAMLD1 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 40/55 reads (73%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.592); catalogued as COSV99475375; called by muse, mutect2, varscan2
- MAP2K3 | c.124del p.R42Gfs*24 (on ENST00000342679 / NM_145109.3; = p.R13Gfs*24 on NM_002756.4) | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | catalogued as rs1567665648, COSV57561353; called by mutect2, pindel, varscan2
- MAP3K20 | c.1305A>G p.I435M | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.201); catalogued as COSV100919325; called by muse, mutect2, varscan2
- MAP3K7 | c.1786A>G p.R596G (on ENST00000369329 / NM_145331.3; = p.R569G on NM_003188.4) | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV100997425; called by muse, varscan2
- MAP4 | c.470G>A p.S157N | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as rs200887208, COSV100805251; called by muse, mutect2, varscan2
- MAPKAPK5 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566269482, COSV101534700; called by muse, mutect2, varscan2
- MAS1L | c.12del p.I6Ffs*59 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as COSV65809765; called by mutect2, pindel, varscan2
- MCEE | c.419del p.K140Rfs*6 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs776473131; called by mutect2, varscan2
- MCF2L2 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs773032244, COSV61055281; called by muse, mutect2, varscan2
- MCM2 | c.2132G>A p.G711D | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0.013); catalogued as COSV99412602, COSV99413714; called by muse, mutect2, varscan2
- MDN1 | c.8073del p.F2691Lfs*7 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | catalogued as rs35107588; called by mutect2, pindel, varscan2
- MED15 | c.1357del p.Q453Sfs*41 (on ENST00000263205 / NM_001003891.3; = p.Q413Sfs*41 on NM_015889.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/15 reads (40%) | catalogued as COSV99487865; called by mutect2, varscan2
- MED16 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as COSV99514935; called by muse, mutect2, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | catalogued as rs762115034; called by mutect2, pindel, varscan2
- MEX3B | c.1037del p.G346Efs*181 | Frame Shift Del (DEL) | VAF 25/71 reads (35%) | catalogued as rs1406688622; called by mutect2, pindel, varscan2
- MFF | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.945); catalogued as rs770994655, COSV100449191; called by muse, mutect2, varscan2
- MICALL1 | c.1247C>T p.T416M | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs759071883, COSV99316906; called by muse, mutect2, varscan2
- MKRN1 | c.1197G>T p.E399D | Missense Mutation (SNP) | VAF 56/145 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.036); catalogued as COSV99751332; called by muse, mutect2, varscan2
- MMS22L | c.1982G>A p.R661Q | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs765975650, COSV51522167; called by muse, mutect2, varscan2
- MNDA | c.1224A>G p.*408Wext*13 | Nonstop Mutation (SNP) | VAF 27/66 reads (41%) | catalogued as COSV63739982; called by muse, mutect2, varscan2
- MOGS | c.881del p.P294Lfs*11 | Frame Shift Del (DEL) | VAF 42/125 reads (34%) | catalogued as rs750486813; called by mutect2, varscan2
- MORC2 | c.1310G>A p.R437Q (on ENST00000397641 / NM_001303256.3; = p.R375Q on NM_014941.3) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.616); catalogued as COSV99309289; called by muse, mutect2, varscan2
- MPPED1 | c.222G>T p.Q74H | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100501092; called by muse, mutect2
- MRPS16 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.741); catalogued as COSV100160012; called by muse, mutect2, varscan2
- MRPS18A | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0.082); catalogued as rs746749172, COSV100928655, COSV100928733; called by muse, mutect2, varscan2
- MRPS25 | c.483del p.K162Sfs*6 | Frame Shift Del (DEL) | VAF 48/158 reads (30%) | catalogued as COSV99507796; called by mutect2, pindel, varscan2
- MRPS9 | c.985A>G p.T329A | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV99305779; called by muse, mutect2, varscan2
- MRTFA | c.1100A>T p.Q367L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV100843769; called by muse, mutect2, varscan2
- MSLNL | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.146); catalogued as rs542987658, COSV99557736; called by muse, varscan2
- MTDH | c.1078A>C p.T360P | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.134); catalogued as COSV100292232; called by muse, mutect2, varscan2
- MTOR | c.3662C>T p.T1221I | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.969); catalogued as COSV100815572; called by muse, mutect2, varscan2
- MTR | c.2350G>A p.V784M | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs940351904, COSV63965178; called by muse, mutect2, varscan2
- MUC16 | c.31742C>T p.P10581L | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as rs368049820, COSV101197269; called by muse, mutect2, varscan2
- MYH10 | c.3227C>T p.A1076V | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.407); catalogued as rs150206681; called by muse, mutect2, varscan2
- MYH13 | c.2387G>A p.C796Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as COSV99351535; called by muse, mutect2, varscan2
- MYLK3 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); catalogued as rs147831842; called by muse, mutect2, varscan2
- MYLK4 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs757508603, COSV99193684; called by muse, mutect2, varscan2
- MYO16 | c.1190T>C p.L397P | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99193387; called by muse, mutect2
- MYO3A | c.4335dup p.L1446Ifs*3 | Frame Shift Ins (INS) | VAF 9/29 reads (31%) | catalogued as rs772558362; called by mutect2, pindel, varscan2
- MYO5A | c.2401C>T p.R801W | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376727710; called by muse, mutect2, varscan2
- MYO7A | c.952A>T p.I318F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101288998; called by muse, mutect2, varscan2
- MYO7A | c.2618G>A p.R873Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.986); catalogued as rs1052032; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYOM2 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.704); catalogued as rs143949365, COSV50701870; called by muse, mutect2, varscan2
- MYRF | c.789dup p.S264Qfs*74 (on ENST00000278836 / NM_001127392.3; = p.S255Qfs*74 on NM_013279.4) | Frame Shift Ins (INS) | VAF 26/78 reads (33%) | catalogued as rs769274302; called by mutect2, varscan2
- NADK2 | c.559C>T p.R187W (on ENST00000381937 / NM_001085411.3; = p.R24W on NM_153013.4) | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773035471, COSV56934989; called by muse, varscan2
- NCKIPSD | c.2066G>A p.R689H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1018892440, COSV53660677; called by muse, mutect2, varscan2
- NCOA2 | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs757931284, COSV71763730; called by muse, mutect2, varscan2
- NCOR1 | c.2446G>A p.A816T | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs76080188, COSV51963410, COSV99246114; called by muse, mutect2, varscan2
- NDUFA5 | c.299G>A p.W100* | Nonsense Mutation (SNP) | VAF 19/69 reads (28%) | catalogued as COSV100864203; called by muse, mutect2, varscan2
- NEB | c.8300G>T p.R2767M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV99413260; called by muse, mutect2, varscan2
- NEDD4 | c.3302A>G p.Y1101C (on ENST00000508342 / NM_001284338.1; = p.Y682C on NM_006154.4) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100163098; called by muse, mutect2, varscan2
- NEK5 | c.11A>G p.Y4C | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as COSV100839079; called by muse, mutect2, varscan2
- NELFCD | c.737C>T p.T246M (on ENST00000602795; = p.T228M on NM_198976.4) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1236829853, COSV59744986; called by muse, mutect2, varscan2
- NEO1 | c.4088C>T p.A1363V | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99981012; called by muse, mutect2, varscan2
- NES | c.1716T>A p.N572K | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.34); catalogued as COSV100957688; called by muse, mutect2, varscan2
- NEXN | c.1630C>T p.Q544* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as COSV99627396; called by muse, mutect2, varscan2
- NID2 | c.3103del p.R1035Gfs*67 | Frame Shift Del (DEL) | VAF 23/64 reads (36%) | catalogued as COSV53499514; called by mutect2, pindel, varscan2
- NINL | c.2549G>A p.R850H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as rs755156661, COSV99624200; called by mutect2, varscan2
- NIPA2 | c.98del p.K33Rfs*12 | Frame Shift Del (DEL) | VAF 26/78 reads (33%) | catalogued as rs145147241; called by mutect2, varscan2
- NKX2-3 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100755014, COSV60728752; called by muse, mutect2, varscan2
- NKX3-2 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as rs778533056, COSV101219794; called by muse, mutect2, varscan2
- NLRC3 | c.3157G>A p.A1053T | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100072249; called by muse, mutect2, varscan2
- NOBOX | c.1322dup p.L442Tfs*35 | Frame Shift Ins (INS) | VAF 6/12 reads (50%) | catalogued as rs753934412; called by mutect2, varscan2
- NPBWR1 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.92); catalogued as COSV100488060; called by muse, mutect2, varscan2
- NPHP1 | c.862G>T p.G288* | Nonsense Mutation (SNP) | VAF 73/179 reads (41%) | catalogued as COSV100337729; called by muse, mutect2, varscan2
- NPHP1 | c.24T>A p.D8E | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs760473645, COSV100337730; called by muse, mutect2, varscan2
- NR1D1 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs148810425; called by muse, mutect2, varscan2
- NR2F1 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV59068177; called by muse, mutect2, varscan2
- NRG2 | c.1862C>T p.T621M | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99179846; called by muse, mutect2, varscan2
- NRIP3 | c.476C>A p.P159H | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100487038; called by muse, mutect2, varscan2
- NRXN1 | c.2720T>C p.V907A | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); catalogued as COSV100452486; called by muse, varscan2
- NSMF | c.1375C>A p.H459N (on ENST00000371475 / NM_001130969.3; = p.H457N on NM_015537.4) | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV99688887; called by muse, mutect2, varscan2
- NSUN3 | c.336dup p.Y113Ifs*49 | Frame Shift Ins (INS) | VAF 18/74 reads (24%) | catalogued as rs1476488662; called by mutect2, pindel, varscan2
- NT5C1B | c.1639C>T p.R547C (on ENST00000359846 / NM_001199086.2; = p.R487C on NM_033253.4) | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs777926079, COSV58397621; called by muse, mutect2, varscan2
- NTN3 | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV99564546; called by muse, mutect2, varscan2
- NUMBL | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs1300068299, COSV99424620; called by muse, mutect2, varscan2
- NUP210 | c.5227A>G p.S1743G | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.985); catalogued as COSV99595282; called by muse, mutect2, varscan2
- NUP214 | c.681del p.V228Sfs*29 | Frame Shift Del (DEL) | VAF 24/64 reads (38%) | catalogued as rs771913112, COSV63912486; called by mutect2, varscan2
- NUTM1 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV100411974; called by muse, mutect2, varscan2
- OBSCN | c.11986G>A p.A3996T | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs746873334, COSV52796380, COSV99470534; called by muse, mutect2, varscan2
- OCA2 | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV62341550; called by muse, mutect2, varscan2
- OPTN | c.76del p.H26Tfs*19 | Frame Shift Del (DEL) | VAF 22/88 reads (25%) | catalogued as rs753966040; called by mutect2, pindel, varscan2
- OR10G3 | c.605T>C p.V202A | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0.08); catalogued as COSV100336048; called by muse, mutect2, varscan2
- OR11H4 | c.497A>G p.Y166C | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs763120530, COSV100197315; called by muse, mutect2, varscan2
- OR13C3 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.325); catalogued as COSV101053219, COSV66166125; called by muse, mutect2, varscan2
- OR2G2 | c.257T>C p.V86A | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV100189490; called by muse, mutect2, varscan2
- OR2M3 | c.506G>A p.C169Y | Missense Mutation (SNP) | VAF 83/204 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV101513383; called by muse, mutect2, varscan2
- OR4C11 | c.779del p.P260Rfs*28 | Frame Shift Del (DEL) | VAF 29/79 reads (37%) | catalogued as rs764963140, COSV56352663, COSV56353360; called by mutect2, pindel, varscan2
- OR4K13 | c.901del p.R301Dfs*71 | Frame Shift Del (DEL) | VAF 10/19 reads (53%) | catalogued as rs749899868, COSV100237879; called by mutect2, pindel, varscan2
- OR4K2 | c.328A>T p.T110S | Missense Mutation (SNP) | VAF 43/333 reads (13%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV100063868; called by muse, mutect2, varscan2
- OR4P4 | c.817del p.Y273Ifs*15 | Frame Shift Del (DEL) | VAF 39/98 reads (40%) | catalogued as rs747154676; called by mutect2, pindel, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as rs755413956; called by mutect2, varscan2
- OR52E8 | c.273C>A p.F91L | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as COSV101189875; called by muse, mutect2, varscan2
- OR5H2 | c.2T>C p.M1? (on ENST00000356526; = p.M6T on NM_001005482.1) | Translation Start Site (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as COSV100788572; called by muse, mutect2, varscan2
- OR6C4 | c.303dup p.A102Cfs*18 | Frame Shift Ins (INS) | VAF 22/70 reads (31%) | catalogued as rs759108361; called by mutect2, varscan2
- OR6C74 | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.331); catalogued as rs1361260903, COSV100667624; called by muse, mutect2, varscan2
- OR8K3 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.023); catalogued as rs771606771, COSV100449616; called by muse, mutect2, varscan2
- OR9A4 | c.535del p.C179Vfs*23 | Frame Shift Del (DEL) | VAF 56/142 reads (39%) | catalogued as rs562194466; called by mutect2, varscan2
- OSCP1 | c.418C>T p.P140S (on ENST00000356637 / NM_001330493.1; = p.P130S on NM_145047.5) | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as COSV99346951; called by muse, mutect2, varscan2
- OTOF | c.5533G>A p.G1845R (on ENST00000272371 / NM_194248.3; = p.G1078R on NM_004802.4) | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99716100; called by muse, mutect2, varscan2
- OXTR | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100373003; called by muse, mutect2, varscan2
- P2RY2 | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60776906; called by muse, mutect2, varscan2
- P2RY4 | c.773T>A p.F258Y | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100996932; called by muse, mutect2, varscan2
- P3H1 | c.763T>C p.Y255H | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as COSV99354672; called by muse, mutect2, varscan2
- P4HTM | c.1469C>A p.A490D (on ENST00000383729 / NM_177939.3; = p.A551D on NM_177938.2) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.154); catalogued as COSV100637497; called by muse, mutect2, varscan2
- PAK5 | c.1058del p.G353Afs*49 | Frame Shift Del (DEL) | VAF 37/112 reads (33%) | catalogued as COSV62028069; called by mutect2, pindel, varscan2
- PAMR1 | c.302dup p.T102Yfs*4 | Frame Shift Ins (INS) | VAF 74/225 reads (33%) | catalogued as rs751755759; called by mutect2, varscan2
- PARD6G | c.92G>T p.R31M | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100783266; called by muse, mutect2, varscan2
- PARVG | c.937T>G p.F313V | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100796010; called by muse, mutect2, varscan2
- PASK | c.1811del p.G604Afs*4 | Frame Shift Del (DEL) | VAF 29/83 reads (35%) | catalogued as rs769655744; called by mutect2, pindel, varscan2
- PBRM1 | c.3553C>T p.R1185* (on ENST00000296302 / NM_001366071.2; = p.R1160* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 31/73 reads (42%) | catalogued as COSV56264314; called by muse, mutect2, varscan2
- PBRM1 | c.1783C>T p.R595W | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs777012889, COSV99966645; called by muse, mutect2, varscan2
- PC | c.1516C>A p.H506N | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV100540578; called by muse, mutect2
- PCARE | c.1273C>T p.R425* | Nonsense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as rs1439930038, CM1511739, COSV59057907; called by muse, mutect2, varscan2
- PCBP2 | c.524dup p.K176Efs*46 | Frame Shift Ins (INS) | VAF 12/34 reads (35%) | catalogued as rs776329515; called by mutect2, varscan2
- PCDH10 | c.1954C>T p.R652W | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs535858980, COSV99992541; called by muse, mutect2, varscan2
- PCDH11X | c.1597G>T p.E533* | Nonsense Mutation (SNP) | VAF 18/34 reads (53%) | catalogued as COSV100006772; called by muse, mutect2, varscan2
- PCDH17 | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.326); catalogued as COSV100931364; called by muse, mutect2, varscan2
- PCDHA13 | c.1924G>A p.A642T | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.509); catalogued as COSV56541117; called by muse, mutect2, varscan2
- PCDHA3 | c.596del p.N199Ifs*2 | Frame Shift Del (DEL) | VAF 22/46 reads (48%) | catalogued as rs782411180, COSV65371489; called by mutect2, varscan2
- PCDHA3 | c.2107G>A p.A703T | Missense Mutation (SNP) | VAF 48/128 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV63540376; called by muse, mutect2, varscan2
- PCDHA9 | c.1354G>A p.A452T | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.135); catalogued as rs145248721; called by muse, mutect2, varscan2
- PCDHB8 | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV99176270; called by muse, mutect2
- PCDHGA6 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.73); catalogued as rs1194415432, COSV53906621; called by muse, mutect2, varscan2
- PCDHGB2 | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs773499284, COSV99527848; called by muse, mutect2, varscan2
- PCDHGC4 | c.1815G>T p.W605C | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99337048; called by muse, mutect2, varscan2
- PCNT | c.4361C>G p.A1454G | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100854913; called by muse, mutect2, varscan2
- PCSK5 | c.1985A>G p.K662R | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV100949272; called by muse, mutect2, varscan2
- PCSK7 | c.1648A>G p.S550G | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99638864; called by muse, mutect2
- PCSK7 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100309079; called by muse, mutect2, varscan2
- PDCD1LG2 | c.515G>A p.G172D | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV101173054; called by muse, mutect2, varscan2
- PDCD6IP | c.602del p.L201* | Frame Shift Del (DEL) | VAF 23/74 reads (31%) | catalogued as rs781474699; called by mutect2, varscan2
- PDE10A | c.1561C>T p.R521W | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs770874774, COSV100604095; called by muse, mutect2, varscan2
- PDE8B | c.914A>G p.H305R | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as CM080493, COSV99365845; called by muse, mutect2, varscan2
- PDIA3 | c.650A>G p.D217G | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as rs1395590299, COSV100294794; called by muse, varscan2
- PDS5B | c.3954del p.K1318Nfs*76 | Frame Shift Del (DEL) | VAF 6/16 reads (38%) | catalogued as rs747131399; called by mutect2, varscan2
- PDZD2 | c.4248del p.S1419Vfs*6 | Frame Shift Del (DEL) | VAF 8/46 reads (17%) | catalogued as rs113511990, COSV56865110; called by mutect2, pindel, varscan2
- PEX5L | c.1538G>A p.R513H | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55841215; called by muse, mutect2, varscan2
- PGBD4 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 26/77 reads (34%) | catalogued as rs1474853461, COSV99854665; called by muse, mutect2, varscan2
- PHACTR1 | c.1193A>G p.E398G | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV100274821; called by muse, mutect2, varscan2
- PHC2 | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as COSV99930570; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 8/21 reads (38%) | catalogued as rs769717544; called by mutect2, varscan2
- PHF20L1 | c.3027G>T p.Q1009H | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99620024; called by muse, mutect2, varscan2
- PHIP | c.878G>A p.G293D | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1390468694, COSV99243162; called by muse, mutect2, varscan2
- PHLDB2 | c.3628A>G p.N1210D (on ENST00000393925 / NM_001134439.2; = p.N1167D on NM_145753.2) | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV99844842; called by muse, mutect2, varscan2
- PIK3C2B | c.2578G>A p.A860T | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs751159224, COSV100915939; called by muse, mutect2, varscan2
- PILRA | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs377572549; called by mutect2, varscan2
- PIM1 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.361); catalogued as rs1244024334, COSV100998561; called by muse, mutect2, varscan2
- PKD1 | c.4232G>A p.R1411H | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as rs371937874; called by muse, mutect2, varscan2
- PKDREJ | c.3157G>A p.A1053T | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.796); catalogued as COSV99478237; called by muse, mutect2, varscan2
- PKHD1L1 | c.2114C>T p.A705V | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.018); catalogued as COSV101005018; called by muse, mutect2, varscan2
- PKIG | c.124A>C p.M42L | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100596036; called by muse, mutect2, varscan2
- PKMYT1 | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.39); catalogued as rs372008941; called by muse, mutect2, varscan2
- PKN3 | c.1984C>T p.R662C | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs765278398, COSV99403171; called by muse, mutect2, varscan2
- PLA2G2F | c.439A>T p.T147S | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.391); catalogued as COSV100907889; called by muse, mutect2, varscan2
- PLAGL2 | c.30dup p.W11Lfs*33 | Frame Shift Ins (INS) | VAF 22/42 reads (52%) | catalogued as rs755627840; called by mutect2, varscan2
- PLAT | c.59T>G p.V20G | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV99534887; called by muse, mutect2, varscan2
- PLCD1 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.928); catalogued as COSV99378229; called by muse, mutect2, varscan2
- PLEC | c.10849A>G p.S3617G (on ENST00000322810 / NM_201380.4; = p.S3507G on NM_000445.5) | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); catalogued as rs989173743, COSV100508950; called by muse, mutect2, varscan2
- PLEC | c.7484C>T p.A2495V (on ENST00000322810 / NM_201380.4; = p.A2385V on NM_000445.5) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs782367691, COSV59616245; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEC | c.4924G>A p.D1642N (on ENST00000322810 / NM_201380.4; = p.D1532N on NM_000445.5) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100508967; called by muse, mutect2, varscan2
- PLEKHA6 | c.381+1G>A p.X127_splice | Splice Site (SNP) | VAF 51/151 reads (34%) | catalogued as COSV99691308; called by muse, mutect2, varscan2
- PLEKHG2 | c.4124G>T p.R1375M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); catalogued as COSV99216579; called by muse, mutect2, varscan2
- PLEKHG4B | c.2683G>A p.V895M (on ENST00000283426; = p.V1251M on NM_052909.5) | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as rs115556780, COSV99359539; called by muse, mutect2, varscan2
- PLEKHM2 | c.2822G>A p.S941N | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.022); catalogued as COSV99606395; called by muse, mutect2, varscan2
- PLK3 | c.1448G>A p.R483H | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as rs779691195, COSV59499248; called by muse, mutect2, varscan2
- PLOD1 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs945232384, COSV99537436; called by muse, mutect2, varscan2
- PLOD2 | c.670G>T p.G224* | Nonsense Mutation (SNP) | VAF 41/114 reads (36%) | catalogued as COSV99282181; called by muse, mutect2, varscan2
- PLP1 | c.811A>G p.M271V | Missense Mutation (SNP) | VAF 75/93 reads (81%) | SIFT tolerated (0.17); PolyPhen benign (0.042); catalogued as COSV100393220; called by muse, mutect2, varscan2
- PLVAP | c.355T>C p.C119R | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99391429; called by muse, mutect2, varscan2
- PLXDC1 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs143709538; called by muse, mutect2, varscan2
- PLXNB2 | c.2575G>A p.V859M | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs780634166, COSV100833758; called by muse, mutect2, varscan2
- PLXNB3 | c.5525A>C p.N1842T | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367877344, COSV100736985; called by muse, mutect2, varscan2
- PLXND1 | c.3892C>T p.R1298* | Nonsense Mutation (SNP) | VAF 32/62 reads (52%) | catalogued as COSV100138801; called by muse, mutect2, varscan2
- PNPLA2 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as rs988744471, COSV100352044, COSV60745415; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PNPLA8 | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1019642712, COSV99993320; called by muse, mutect2, varscan2
- POF1B | c.1165C>G p.Q389E | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99425808; called by muse, mutect2, varscan2
- POLE3 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.152); catalogued as COSV55912646; called by muse, mutect2, varscan2
- POLM | c.290dup p.A98Sfs*73 | Frame Shift Ins (INS) | VAF 26/76 reads (34%) | catalogued as rs745933237; called by mutect2, varscan2
- POLR2G | c.383A>T p.Y128F | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.062); catalogued as COSV100079993; called by muse, mutect2, varscan2
- POM121 | c.2923G>A p.A975T (on ENST00000434423; = p.A710T on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs782328273, COSV99987312; called by muse, mutect2, varscan2
- PPCS | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs1291974534, COSV100999486; called by muse, mutect2, varscan2
- PPM1D | c.1535del p.N512Ifs*2 | Frame Shift Del (DEL) | VAF 25/83 reads (30%) | catalogued as rs763475304; called by mutect2, pindel, varscan2
- PPP1R13L | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs1340761762, COSV100714625; called by muse, mutect2, varscan2
- PPP1R26 | c.1673G>A p.C558Y | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.94); PolyPhen benign (0.188); catalogued as rs1343194663, COSV100777951; called by muse, mutect2, varscan2
- PPP1R32 | c.947del p.K316Rfs*27 | Frame Shift Del (DEL) | VAF 52/190 reads (27%) | catalogued as rs1364065174, COSV58545076; called by mutect2, pindel, varscan2
- PPP1R3A | c.848A>G p.Y283C | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.205); catalogued as COSV99491604; called by muse, mutect2, varscan2
- PPP4R3A | c.455C>A p.P152H | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV100465404; called by muse, mutect2, varscan2
- PRB3 | c.187C>A p.Q63K | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.188); catalogued as rs1452733039, COSV99685391; called by muse, mutect2, varscan2
- PRG2 | c.394A>G p.N132D | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV100314802; called by muse, mutect2, varscan2
- PRKCE | c.1162A>C p.S388R | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100076082; called by muse, mutect2, varscan2
- PRKCI | c.826del p.T276Qfs*7 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs753143066; called by mutect2, varscan2
- PRPF40A | c.2644dup p.R882Kfs*15 | Frame Shift Ins (INS) | VAF 8/36 reads (22%) | catalogued as rs1464958512; called by mutect2, varscan2
- PRPF8 | c.1808G>A p.R603H | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1378204722, COSV100516957; called by muse, mutect2, varscan2
- PRRC2C | c.4553del p.N1518Mfs*4 (on ENST00000367742; = p.N1516Mfs*4 on NM_015172.4) | Frame Shift Del (DEL) | VAF 21/43 reads (49%) | catalogued as rs759081735; called by mutect2, varscan2
- PRRG1 | c.401del p.P134Hfs*19 | Frame Shift Del (DEL) | VAF 46/60 reads (77%) | catalogued as rs781858060; called by mutect2, varscan2
- PRSS36 | c.2038del p.L680Wfs*6 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as rs771809480; called by mutect2, pindel
- PRSS55 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141913017; called by muse, mutect2, varscan2
- PRX | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs770713710, COSV99397283; called by muse, mutect2, varscan2
- PSG5 | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 89/250 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV100742503; called by muse, mutect2, varscan2
- PSMD2 | c.677A>G p.Y226C | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as rs990768776, COSV100031441; called by muse, mutect2, varscan2
- PSME4 | c.4795C>A p.L1599I | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.279); catalogued as COSV101122145; called by muse, mutect2, varscan2
- PTBP2 | c.1544A>G p.Q515R (on ENST00000426398 / NM_001300986.2; = p.Q506R on NM_021190.4) | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as COSV100930144, COSV64626866; called by muse, mutect2, varscan2
- PTGS1 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.437); catalogued as rs767143547, COSV99792782; called by muse, mutect2, varscan2
- PTPA | c.467C>A p.A156D (on ENST00000337738 / NM_178001.2; = p.A121D on NM_021131.5) | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV100533899; called by muse, mutect2, varscan2
- PTPRF | c.4741A>G p.T1581A | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100740370; called by muse, mutect2, varscan2
- PTPRO | c.1213G>T p.G405* | Nonsense Mutation (SNP) | VAF 27/67 reads (40%) | catalogued as COSV55502953, COSV99839246; called by muse, mutect2, varscan2
- PTPRT | c.2482A>G p.N828D | Missense Mutation (SNP) | VAF 187/474 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as COSV100623980; called by muse, mutect2, varscan2
- PTPRU | c.4205G>A p.C1402Y | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV100111192; called by muse, mutect2, varscan2
- PYY | c.17G>T p.R6M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV100778825; called by muse, mutect2, varscan2
- QTRT2 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs535717568, COSV55558966; called by muse, mutect2, varscan2
- RAB11FIP4 | c.881T>C p.L294P | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100364986; called by muse, mutect2, varscan2
- RAB13 | c.125-1G>T p.X42_splice | Splice Site (SNP) | VAF 19/51 reads (37%) | catalogued as COSV100885189; called by muse, mutect2, varscan2
- RADIL | c.1244A>T p.D415V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101271180; called by mutect2, varscan2
- RAI1 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs1424544991, COSV99883013; called by muse, mutect2, varscan2
- RAI1 | c.3919C>T p.R1307W | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs367703186, COSV55395743; called by muse, mutect2, varscan2
- RAPGEF2 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as rs778562452, COSV100030375; called by muse, mutect2, varscan2
- RASAL3 | c.506G>A p.G169D | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.04); catalogued as COSV100640249; called by muse, mutect2, varscan2
- RASGEF1B | c.94T>C p.Y32H | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100020814; called by muse, mutect2, varscan2
- RASGEF1C | c.1004C>T p.T335M | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs145725435; called by muse, mutect2, varscan2
- RASSF7 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368113813; called by muse, mutect2, varscan2
- RBBP6 | c.4603A>G p.S1535G | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.542); catalogued as rs1482033615, COSV100154085; called by muse, mutect2, varscan2
- RBFOX1 | c.1060G>A p.V354I | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.11); catalogued as rs138704494, COSV60951805; called by muse, mutect2, varscan2
- RBM11 | c.29G>T p.R10M | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101271162; called by muse, mutect2, varscan2
- RBM14 | c.1964A>G p.Y655C | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100036459; called by muse, mutect2, varscan2
- RBM25 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.198); catalogued as rs1218930370, COSV56199207; called by muse, mutect2, varscan2
- RBM43 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100508434; called by muse, mutect2, varscan2
- RDH13 | c.289G>A p.D97N (on ENST00000415061 / NM_001145971.2; = p.D26N on NM_138412.4) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV99401310; called by muse, mutect2, varscan2
- RDX | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as rs764536750, COSV100562675; called by muse, mutect2, varscan2
- REEP4 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 19/97 reads (20%) | catalogued as rs760225107, COSV100097985; called by muse, mutect2, varscan2
- RELT | c.581C>T p.T194M | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs775696442, COSV50362308, COSV50362358; called by muse, mutect2, varscan2
- RESF1 | c.3166T>C p.S1056P | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100439980; called by muse, mutect2, varscan2
- RFT1 | c.312G>A p.W104* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as COSV99965278; called by muse, mutect2, varscan2
- RFTN1 | c.1399A>G p.S467G | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs1275146994, COSV100488521; called by muse, mutect2, varscan2
- RGL2 | c.2227G>A p.V743I | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs770506486, COSV101004690; called by muse, mutect2, varscan2
- RGL2 | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101004691; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 26/54 reads (48%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RIC3 | c.326dup p.L109Ffs*9 | Frame Shift Ins (INS) | VAF 12/48 reads (25%) | catalogued as rs746684945; called by mutect2, varscan2
- RIMS2 | c.824A>G p.D275G (on ENST00000666250 / NM_001348490.2; = p.D83G on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.957); catalogued as COSV99153310; called by muse, mutect2, varscan2
- RIOK1 | c.189_191dup p.D69dup | In Frame Ins (INS) | VAF 12/52 reads (23%) | catalogued as rs764932797; called by mutect2, pindel, varscan2
- RIOX1 | c.1528C>A p.L510M | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as COSV100407849; called by muse, mutect2, varscan2
- RMI1 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.253); catalogued as rs1241733025, COSV100365958, COSV57937752; called by muse, mutect2, varscan2
- RND1 | c.486A>T p.E162D | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.173); catalogued as COSV100552050; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 32/127 reads (25%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RP1L1 | c.6285G>T p.Q2095H | Missense Mutation (SNP) | VAF 68/239 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.333); catalogued as COSV101222817; called by muse, mutect2, varscan2
- RPAP1 | c.2663C>A p.A888D | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.44); PolyPhen benign (0.077); catalogued as COSV100426790; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 35/46 reads (76%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPTN | c.515A>G p.Q172R | Missense Mutation (SNP) | VAF 100/364 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100285141; called by muse, mutect2
- RPUSD2 | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100225045, COSV100225233; called by muse, mutect2, varscan2
- RREB1 | c.4749_4751del p.E1583del | In Frame Del (DEL) | VAF 7/37 reads (19%) | catalogued as rs1201445056; called by pindel, varscan2
- RRP12 | c.3880G>T p.D1294Y | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.161); catalogued as COSV100212787; called by muse, mutect2, varscan2
- RRP9 | c.1228C>T p.R410W | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs745791944, COSV99232044; called by muse, mutect2, varscan2
- RSPH6A | c.1402G>A p.V468I | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs149814820; called by muse, mutect2, varscan2
- RSU1 | c.494G>T p.R165M | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100590067; called by muse, mutect2, varscan2
- RTN3 | c.3089del p.K1030Rfs*67 (on ENST00000377819 / NM_001265589.2; = p.K234Rfs*67 on NM_006054.4) | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs747510098; called by mutect2, varscan2
- RTTN | c.5744del p.K1915Rfs*9 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | catalogued as rs756606313; called by mutect2, varscan2
- RUFY1 | c.335A>C p.E112A | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100105566, COSV60158491; called by muse, mutect2, varscan2
- RUNDC1 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100865749; called by muse, mutect2, varscan2
- RUSC2 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.1); catalogued as COSV100770547; called by muse, mutect2, varscan2
870 further variants in this file (474 protein-altering or splice-affecting, 353 silent, 43 other) are not listed here.
